Surgical pathology report (de-identified scan), TCGA case TCGA-DG-A2KL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Ontario Institute for Cancer Research, specimen TCGA-DG-A2KL-01A (Primary Tumor).

Sample Type TUMOUR

Sample Preparation

Fresh Frozen

Site of Primary (Event)

Cervical

Site of Tissue

9:00 position - cervix

Year of Sample Collection

Age at Sample Collection (yrs)

Sample Comments

Days to Procedure Date

Days to Diagnosis

Type of Procedure

Site of Primary (Histology)

Bilateral Disease

Tumour Size (cm)

Histology

Grade/Differentiation

Pathological T

Pathological N

Number of Nodes Sampled

Number of Nodes Positive

Clinical M

Histology Comments

Margin is positive for squamous cell carcinoma, invasive-type.

0

11

Surgical resection

Cervix

NO

5.5

Squamous cell carcinoma, keratinizing

Grade I (Well differentiated)

T2,NOS

NO

0

8

MX

Of note: Spec#4: Rt. posterior vaginal margin, excision:

1CD-0-3

carcinoma, squamous cell,
keratinizing, NOS, 8071/3

Site: cervix, NOS C53.9

lw 8/23/11

Source: NCI Genomic Data Commons file 51ce0dcc-849b-4777-86d6-89ad3873ca35 (TCGA-DG-A2KL.A0EED671-A0A6-4F3E-86B2-AB8277B134ED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).